Somatic mutation profile of tumor specimen TCGA-NG-A4VW-01A (aliquot TCGA-NG-A4VW-01A-11D-A28R-08) from TCGA case TCGA-NG-A4VW, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Age at diagnosis: 74.8 years (27,326 days).
Specimen TCGA-NG-A4VW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 578f70be-98f2-4d5d-8efb-6ea83d52c2d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NG-A4VW-10A (Blood Derived Normal), aliquot TCGA-NG-A4VW-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08b1a883-e20f-467b-9b5a-7d384048ddb8

The open-access MAF lists 50 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Nonsense Mutation 5, Frame Shift Del 2, Intron 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL17A1 | c.3908G>A p.R1303Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.143); catalogued as rs121912771, CM970345; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM131938, COSV64289920, COSV64290011, COSV64297199; called by muse, mutect2, varscan2
- PTEN | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 30/102 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779530981, CM033666, COSV64288954, COSV64292660; called by muse, mutect2, varscan2
- WNT10A | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374910216; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200280095, COSV55957617; called by muse, mutect2, varscan2
- C19orf57 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as rs527426427; called by muse, mutect2, varscan2
- CNGA3 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV55622229; called by muse, mutect2, varscan2
- CSF2RA | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as rs759171777; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUX1 | c.439C>T p.R147* (on ENST00000292535 / NM_181552.4; = p.R158* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 34/168 reads (20%) | catalogued as rs782297523, COSV52890867; called by muse, mutect2, varscan2
- EML4 | c.1350T>G p.F450L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755601518; called by muse, mutect2, varscan2
- FUT1 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1229284545, CM004475, COSV59569266; called by muse, mutect2, varscan2
- GLRX2 | c.161C>A p.T54K (on ENST00000367439 / NM_197962.3; = p.T55K on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs535022976, COSV66471758; called by muse, mutect2, varscan2
- GRID1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769943428; called by muse, mutect2, varscan2
- HECW1 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780022640; called by muse, mutect2, varscan2
- LGR5 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1350286218; called by mutect2, varscan2
- MYOM3 | c.3621C>T p.D1207= | Splice Region (SNP) | VAF 13/86 reads (15%) | catalogued as rs372739261; called by muse, mutect2, varscan2
- PRR27 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs577881430, COSV60641128; called by muse, mutect2
- RB1 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as CM159958, COSV57297232, COSV57309807; called by muse, mutect2, varscan2
- SOWAHD | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.096); catalogued as rs764690174, COSV59649948; called by muse, mutect2, varscan2
- SOX8 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99559411; called by muse, mutect2, varscan2
- SPCS2 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.083); catalogued as rs573769844; called by muse, mutect2, varscan2
- SSRP1 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186583601; called by muse, mutect2, varscan2
- ZBTB7B | c.1087C>T p.R363C (on ENST00000292176; = p.R397C on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52692535; called by muse, varscan2
- ZNF415 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138480197; called by mutect2, varscan2
- CCDC33 | c.1588C>T p.Q530* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- F13A1 | c.515dup p.T173Nfs*18 | Frame Shift Ins (INS) | VAF 17/126 reads (13%) | called by mutect2, pindel, varscan2
- FLNA | c.2258G>C p.S753T | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- INAVA | c.1398C>A p.H466Q | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- MAD1L1 | c.210del p.M72Cfs*5 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, pindel, varscan2
- NDRG3 | c.131T>C p.V44A (on ENST00000349004 / NM_032013.4; = p.V32A on NM_022477.4) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- PSMG2 | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- RXFP1 | c.2109A>C p.K703N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIN3A | c.2698C>T p.Q900* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- TAF7 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TLE1 | c.1578_1581del p.C526* | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel
- TNIP1 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZBTB7B | c.1079A>G p.K360R (on ENST00000292176; = p.K394R on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, varscan2
- ABCA8 | c.4035C>T p.A1345= | Silent (SNP) | VAF 44/290 reads (15%) | catalogued as rs1183759222, COSV52197297; called by muse, mutect2, varscan2
- COL5A1 | c.1977C>T p.D659= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs370766020; ClinVar: benign; called by muse, mutect2, varscan2
- COPRS | c.240T>C p.F80= | Silent (SNP) | VAF 49/339 reads (14%) | called by muse, mutect2, varscan2
- CR1 | c.5409C>T p.C1803= | Silent (SNP) | VAF 83/225 reads (37%) | catalogued as rs749885738, COSV65457602; called by muse, mutect2, varscan2
- DHCR7 | c.51C>T p.G17= | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as rs776713087, COSV62794419; called by muse, mutect2, varscan2
- FLNA | c.7209C>T p.D2403= (on ENST00000369850 / NM_001110556.2; = p.D2395= on NM_001456.3) | Silent (SNP) | VAF 57/295 reads (19%) | catalogued as rs781906091; called by muse, mutect2, varscan2
- GAS2L2 | c.1233C>T p.L411= | Silent (SNP) | VAF 30/191 reads (16%) | catalogued as rs1212093051; called by muse, mutect2, varscan2
- NR6A1 | c.780C>T p.A260= (on ENST00000487099 / NM_033334.4; = p.A255= on NM_001489.5) | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs780379141; called by muse, mutect2, varscan2
- TMPRSS7 | c.2241C>T p.L747= (on ENST00000452346; = p.L621= on NM_001042575.2) | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs768601194; called by muse, mutect2, varscan2
- WSCD1 | c.1401C>T p.Y467= | Silent (SNP) | VAF 44/285 reads (15%) | catalogued as rs369854579; called by muse, mutect2, varscan2
- CLLU1 | n.1977-908G>A | Intron (SNP) | VAF 7/47 reads (15%) | catalogued as rs779451716, COSV65903108, COSV65903303; called by muse, mutect2, varscan2
- NACA | c.71-1263C>T | Intron (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
